Gene-level copy-number profile of tumor specimen ALCH-B1U3-TTP1-A from ALCHEMIST case ALCH-B1U3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.8 years (23,315 days).
Specimen ALCH-B1U3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e8ba86ff-ceae-4c09-912f-934bc67caa85.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1U3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/e2221cfd-dbb5-4e50-a51f-bdc046d2cdff

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 70; copy number 1: 8,728; copy number 2: 48,552; copy number 3: 1,507; copy number 4: 10; copy number 5: 17; copy number 6: 2; copy number 7: 8; copy number 8: 1; copy number 9: 1; copy number 12: 4; copy number 16: 1; copy number 48: 2.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,049,203–2,185,395, 4 genes (within-gene range 0–1): AL391845.1, PRKCZ, AL590822.2, PRKCZ-AS1.
- chr2:130,139,287–130,182,750, 2 genes (within-gene range 0–2): CCDC74B, SMPD4.
- chr7:140,404,058–140,435,787, 2 genes (within-gene range 0–2): RAB19, AC069335.1.
- chr9:35,906,202–35,907,136, 1 gene: HRCT1.
- chr12:10,212,458–10,223,128, 2 genes: GABARAPL1, GABARAPL1-AS1.
- chr13:19,152,567–19,187,618, 4 genes: SMPD4P2, AL139327.3, TUBA3C, AL139327.1.
- chr13:110,641,412–110,713,603, 1 gene (within-gene range 0–1): CARS2.
- chr14:99,481,169–99,604,207, 4 genes (within-gene range 0–1): CCNK, CCDC85C, AL110504.1, Y_RNA.
- chr14:100,319,073–100,354,061, 3 genes (within-gene range 0–1): RN7SL523P, SLC25A47, AL157871.4.
- chr14:100,339,832–100,340,554, 1 gene (within-gene range 0–1): AL157871.2.
- chr16:31,043,150–31,074,240, 4 genes: AC135050.3, AC135050.1, ZNF668, AC135050.4.
- chr17:16,380,798–16,391,882, 3 genes: UBB, AC093484.3, FTLP12.
- chr18:23,024,596–23,024,703, 1 gene (within-gene range 0–2): Y_RNA.
- chr22:18,527,802–18,577,968, 2 genes: TMEM191B, PI4KAP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 34 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:244,835,616–244,865,272, 3 genes, copy number 5: COX20, HNRNPU, BX323046.1.
- chr4:49,579,833–49,589,529, 2 genes, copy number 48: AC119751.4, SNX18P25.
- chr7:75,395,063–75,410,996, 1 gene, copy number 7 (within-gene range 1–7): TRIM73.
- chr22:18,178,038–18,345,899, 2 genes, copy number 5: FAM230D, GGTLC5P.
- chr22:18,400,407–18,512,187, 4 genes, copy number 12: PPP1R26P3, FAM230A, AC023490.2, FAM247B.
- chr22:18,605,355–18,653,617, 7 genes, copy number 5: AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.
- chr22:21,114,607–21,345,258, 14 genes, copy number 5–16 (within-gene range 2–16): AP000550.1, POM121L7P, E2F6P2, FAM230B, AP000550.2, FAM247A, GGT2, AP000550.3, E2F6P3, POM121L8P, BCRP6, FAM230H, AP000552.2, PPP1R26P5.
- chr22:21,370,064–21,371,945, 1 gene, copy number 9: AP000552.1.

Autosomal genes at a single copy (total copy number 1): 5,919. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
